Surgical pathology report (de-identified scan), TCGA case TCGA-10-0937, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0937-01A (Primary Tumor).

[page 1 of 2]
-
- (A) OMENTUM:
HIGH-GRADE SEROUS CARCINOMA.
- (B) RIGHT FALLOPIAN TUBE AND OVARY:
OVARY, HIGH-GRADE SEROUS CARCINOMA. (SEE COMMENT)
FALLOPIAN TUBE, MESOSALPINGEAL INVOLVEMENT BY HIGH-GRADE SEROUS CARCINOMA.
- (C) LEFT FALLOPIAN TUBE AND OVARY:
OVARY, HIGH-GRADE SEROUS CARCINOMA.
Fallopian tube, no tumor present.
- (D) UTERUS AND CERVIX:
HIGH-GRADE SEROUS CARCINOMA INVOLVING UTERINE SEROSA.
Proliferative endometrium with adjacent benign endometrial polyp.
Myometrial leiomyoma.
Cervix, squamous metaplasia.
- (E) CUL-DE-SAC TUMOR:
HIGH-GRADE SEROUS CARCINOMA.
- (F) SIGMOID COLON:
HIGH-GRADE SEROUS CARCINOMA INVOLVING SEROSA AND PERICOLIC ADIPOSE TISSUE.
Colon resection margins free of tumor.
-

GROSS DESCRIPTION

- (A) OMENTUM - A piece of omentum infiltrated by tumor. The overall specimen dimensions are 14.5 x 8.5 x 1.5 cm. Tumor comprises approximately 40-50% of the specimen volume. The areas of tumor have a solid pale-gray to white cut surface and are interspersed within fat lobules, imparting a firm consistency to the specimen.
SECTION CODE: A1-A3, representative frozen section; A4-A8, additional representative sections of tumor.
*FS/DX: SEROUS CARCINOMA, MOST LIKELY HIGH GRADE.
- (B) RIGHT TUBE, RIGHT OVARY - A tumor distorted right ovary, 4.0 x 4.5 x 2.5 cm and a fallopian tube which is 6.2 cm long with a diameter of 1.5 cm. The fallopian tube has a surface nodule measuring 0.9 x 0.8 x 0.3 cm. Otherwise, the fallopian tube surface is purple-gray and smooth.
The ovary is approximately 40% replaced by a solid tan, fleshy tumor with a friable consistency. The remainder of the ovarian parenchyma is pink-tan with a hemorrhagic 1.3 cm corpus luteum cyst identified. There is a 0.1 to 0.2 cm thick rim of white ovarian cortical tissue around the uninvolved ovarian parenchyma.
SECTION CODE: B1, ovary with corpus luteum cyst; B2, ovary with corpus luteum cyst; B3, B4, ovary with tumor; B5, B6, representative sections of fallopian tube.
- (C) LEFT TUBE AND OVARY - The specimen consists of left adnexal tissue. There is a 5.5 cm long fallopian tube with a

[page 2 of 2]
[REDACTED]

diameter of 0.9 cm. The left ovary measures 3.5 x 2.5 x 1.6 cm and has a tan to white mottled external surface. There is a 1.5 x 1.0 x 1.2 cm white solid nodule with a friable cut surface arising adjacent to (possibly within) the ovarian parenchyma. This nodule appears circumscribed. The outer surface of the ovary is covered by a white to tan layer of tumor, 0.1 to 0.2 cm in thickness. The ovarian parenchyma is pink-tan with a 1.2 cm fluid-filled cyst identified, as well as a 0.7 cm corpus luteum cyst. No lesions are grossly identified on the fallopian tube surface. A representative portion of the solid nodule is submitted to the tumor bank.

SECTION CODE: C1, ovary; C2, ovarian nodule; C3 is ovary and representative section of nodule; C4 is ovary; C5, fallopian tube; C6, ovarian cyst. [REDACTED]
(D) UTERUS, CERVIX - A hysterectomy specimen (10.2 x 7.2 x 5.9 cm). The serosa has a tumor nodule at the posterior peritoneal reflection measuring 2.5 x 2.5 x 1.2 cm. The anterior serosa has a large irregular plaque-like area measuring 5.5 x 5.5 cm up to 0.3 cm in thickness.

The endometrium is 0.3 cm in thickness. On the posterior wall of the uterus is a 0.4 x 0.3 x 0.3 cm endometrial polyp. The myometrium is tan and unremarkable except for four white whorled nodules ranging from 0.5 to 2.0 cm in greatest dimension. The largest is calcified and does not permit sectioning with the scalpel blade. The second largest measures 1.5 cm in greatest dimension and has a rubbery pink-tan cut surface.

The exocervix is smooth, tan glistening and unremarkable.
SECTION CODE: D1, posterior endometrial polyp and posterior endometrium; D2, posterior cervix; D3, lower uterine segment and serosal tumor, posterior; D4, tumor at posterior peritoneal reflection; D5, posterior endometrium; D6, anterior cervix; D7, anterior endometrium; D8, anterior serosa; D9, anterior lower uterine segment; D10, anterior serosa. [REDACTED]

(E) CUL-DE-SAC TUMOR - Multiple tan-white irregular fragments of tissue (7.0 x 5.0 x 2.0 cm) in aggregate. Representative sections in cassettes E1-E3. [REDACTED]
(F) SIGMOID COLON - A segment of sigmoid colon measures 11.0 cm in length with attached pericolic adipose tissue. Multiple irregular lesions were identified on the surface of the colon invading the submucosa of colon. Colonic mucosa is unremarkable. Tumor nodule is abutting to one resection soft tissue margin. Multiple lesions measure ranging from 1.0 x 1.0 x 0.5 cm up to 6.0 x 5.0 x 3.0 cm. Multiple lymph nodes were identified in the pericolic adipose tissue measures ranging from 0.2 x 0.2 x 0.2 cm up to 1.0 x 0.7 x 0.5 cm. Representative sections are submitted.

INK CODE: Black - surface of the specimen.
SECTION CODE: F1, entire shaved section from one of the resection margins; F2-F3, entirely shaved section from the other resection margin; F4-F7, representative section from the largest lesion; F8-F13, representative section from other different nodules; F14-F23, six possible lymph nodes for each; F24, four possible lymph nodes. [REDACTED]

CLINICAL HISTORY

None given.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file ccf4febe-6f27-4555-b13e-546bb3b74721 (TCGA-10-0937.2A86DCB5-1AF7-447D-B20F-EEF4972048A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).